Somatic mutation profile of tumor specimen TCGA-FW-A3R5-06A (aliquot TCGA-FW-A3R5-06A-11D-A23B-08) from TCGA case TCGA-FW-A3R5, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 69.9 years (25,535 days).
Specimen TCGA-FW-A3R5-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 512edd41-5baa-4c77-9a7c-684ef708b18b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FW-A3R5-10A (Blood Derived Normal), aliquot TCGA-FW-A3R5-10A-01D-A23B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75047559-01f2-4146-95a8-ae679491df62

The open-access MAF lists 22,424 somatic variants for this specimen: 14,025 protein-altering or splice-affecting, 7,878 silent, 521 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13,001, Silent 7,878, Nonsense Mutation 694, Intron 209, Splice Region 163, RNA 162, Splice Site 127, 5'UTR 40, 3'UTR 40, 5'Flank 37, 3'Flank 33, Translation Start Site 22.

Variants (750 of 22,424; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.1987G>A p.G663S | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72653780, CM073963, COSV52741710; ClinVar: pathogenic; called by muse, varscan2
- AGXT | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs180177173, CM072843, COSV56754157; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANK1 | c.4462C>T p.R1488* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as rs777701149, CM032180, COSV55872404; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AR | c.2086G>A p.D696N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555995840, CM102206, CM910044, CM910045, COSV65957302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID2 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 49/145 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57595738; called by muse, mutect2, varscan2
- ASPM | c.4732C>T p.R1578* | Nonsense Mutation (SNP) | VAF 20/99 reads (20%) | catalogued as rs753406334, COSV54125634; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 16/69 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138398778, CM0910483, COSV53723836, COSV53775938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRAF | c.1526G>A p.G509E (on ENST00000288602 / NM_001374244.1; = p.G469E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRIP1 | c.2053C>T p.Q685* | Nonsense Mutation (SNP) | VAF 72/223 reads (32%) | catalogued as rs876659533, COSV51999927; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CASR | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 64/236 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs104893689, CM930077, COSV56137698; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDC45 | c.1660C>T p.R554W | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778665661, COSV54245132; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CFTR | c.3196C>T p.R1066C | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs78194216, CM1212243, CM920175, CM952054, COSV50055196; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLCN1 | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 43/140 reads (31%) | catalogued as rs1337473924, CM950268, COSV58367883; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CNGB3 | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as rs768345097, CM050551, COSV60686900; ClinVar: likely pathogenic; called by muse, varscan2
- COL17A1 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 26/67 reads (39%) | catalogued as rs121912774, CM001969, COSV62225489; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL1A2 | c.2575G>A p.G859S | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs72658200, CM042017, COSV51958577; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A3 | c.3210+1G>A p.X1070_splice | Splice Site (SNP) | VAF 5/29 reads (17%) | catalogued as rs1553762314, CS1312547, COSV59258120; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.2732G>A p.G911E | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104886363, CM003667, COSV60362117; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL6A3 | c.4390C>T p.R1464* | Nonsense Mutation (SNP) | VAF 21/60 reads (35%) | catalogued as rs912671116, COSV55090355; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CP | c.607+1G>A p.X203_splice | Splice Site (SNP) | VAF 31/106 reads (29%) | catalogued as rs386134136, CS035025, COSV52830793; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CREBBP | c.4078C>T p.R1360* | Nonsense Mutation (SNP) | VAF 8/79 reads (10%) | catalogued as rs587783490, CM093602, COSV52117620; ClinVar: pathogenic; called by mutect2, varscan2
- DEPDC5 | c.3502C>T p.R1168* (on ENST00000400246; = p.R1237* on NM_014662.5) | Nonsense Mutation (SNP) | VAF 45/137 reads (33%) | catalogued as rs886039268, CM134017, COSV56698057; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.7755G>A p.W2585* | Nonsense Mutation (SNP) | VAF 22/39 reads (56%) | catalogued as rs762394978, CD159993, CM066783, COSV100627685, COSV58912282; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNM2 | c.1856C>T p.S619L (on ENST00000355667 / NM_001005360.3; = p.S615L on NM_004945.3) | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs121909095, CM076154, CM076155, COSV58960962; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DSG2 | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs371146201; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- DYSF | c.237-1G>A p.X79_splice | Splice Site (SNP) | VAF 71/254 reads (28%) | catalogued as rs1553518087, COSV50342959; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DYSF | c.5904G>A p.W1968* | Nonsense Mutation (SNP) | VAF 16/68 reads (24%) | catalogued as rs1553420848, COSV50352167; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EPHB1 | c.2227C>T p.R743W | Missense Mutation (SNP) | VAF 44/238 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746798014, COSV67657824; called by muse, varscan2
- EPHB1 | c.2228G>A p.R743Q | Missense Mutation (SNP) | VAF 25/222 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs1338928289, COSV67655119; called by muse, varscan2
- F11 | c.1390C>T p.Q464* | Nonsense Mutation (SNP) | VAF 60/157 reads (38%) | catalogued as rs1057517035, COSV53002091; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.6388G>A p.E2130K | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs794728334, CM067392, COSV57317339; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- FREM2 | c.5920G>A p.E1974K | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs121434355, COSV54838575; ClinVar: pathogenic; called by muse, mutect2, varscan2
- G6PC | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs104894568, CM960670, COSV53831058; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GAA | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121907937, CM082740, CM910166, COSV56408643; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- GJB2 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as rs397516875, CM014194, COSV67010710; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- GLB1 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756878418, CM051078, COSV56563900; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GNAI2 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs137853226, COSV56492973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GRID2 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as rs368143665, COSV56207880; ClinVar: likely pathogenic; called by muse, varscan2
- HACE1 | c.2242C>T p.R748* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as rs869025281, CM1512806, COSV53502635; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HADHB | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780351691, CM031199, COSV58546271; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HSD11B1 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 36/108 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54825714, COSV99808085; called by muse, mutect2, varscan2
- IKZF1 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs1245618829, COSV100498631, COSV58784478; ClinVar: likely pathogenic; called by muse, varscan2
- IL17RA | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 24/81 reads (30%) | catalogued as rs1057518745, COSV60053486; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNA2 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876657389, CM152575, COSV60370039; ClinVar: pathogenic; called by muse, varscan2
- KDR | c.3095G>A p.R1032Q | Missense Mutation (SNP) | VAF 29/125 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190050670, COSV55758808; called by muse, mutect2, varscan2
- LHCGR | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs121912529, CM981202, COSV54297266; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MARCHF10 | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 49/178 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs17853369, COSV60886636; called by muse, mutect2, varscan2
- MECP2 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 45/73 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs61751450, CM001234, COSV57654028; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MLC1 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs281875309, CM061852, COSV61116650; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYCN | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057517770, COSV55258811; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.2791G>A p.E931K | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1131691514, CM042419, COSV62519497; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYO18B | c.3053C>T p.P1018L | Missense Mutation (SNP) | VAF 32/112 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.141); catalogued as rs753198702, COSV100123566, COSV59124221; called by muse, varscan2
- NCR1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 49/149 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV52555848; called by muse, mutect2, varscan2
- NF1 | c.1039C>T p.Q347* | Nonsense Mutation (SNP) | VAF 45/118 reads (38%) | catalogued as rs1555610910, CS086356, COSV62204363; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.3712G>T p.E1238* | Nonsense Mutation (SNP) | VAF 90/230 reads (39%) | catalogued as rs1060500346, COSV62204375; ClinVar: pathogenic; called by muse, varscan2
- NGLY1 | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 23/122 reads (19%) | catalogued as rs146140738, COSV54984601; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NLRP3 | c.2753G>A p.R918Q | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs1553293095, CM1510782, COSV60224775; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- NOD2 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs104895477, CM051409, CM1414276, COSV56050957; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OTOGL | c.574C>T p.R192* (on ENST00000547103; = p.R183* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 24/71 reads (34%) | catalogued as rs397514588, CM1210228, COSV72006650; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OXA1L | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 62/200 reads (31%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.11); PolyPhen benign (0.208); catalogued as rs773412250, COSV53536555; called by muse, varscan2
- PDHA1 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs863224147, CM961098, COSV58825380, COSV58827746; ClinVar: pathogenic; called by muse, mutect2, varscan2
- S100A3 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 33/120 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.358); catalogued as rs571596892, COSV62876526, COSV62876899; called by muse, mutect2
- SCN1A | c.5275C>T p.P1759S (on ENST00000303395 / NM_001202435.3; = p.P1748S on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/341 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1064794630, COSV57670879; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.4886G>A p.R1629Q (on ENST00000333535 / NM_198056.3; = p.R1628Q on NM_000335.5) | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs199473623, CM100748, COSV61115745; ClinVar: not provided / pathogenic / likely pathogenic; called by muse, varscan2
- TCF20 | c.2443C>T p.P815S | Missense Mutation (SNP) | VAF 32/104 reads (31%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.996); catalogued as COSV59491282; called by muse, mutect2, varscan2
- THSD7B | c.1669G>A p.G557R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55688858; called by muse, varscan2
- TMEM94 | c.2734C>T p.R912* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as rs557746506, COSV100050031; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 30/76 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as rs587782705, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP63 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 16/76 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761885185, COSV53196562, COSV53210463; called by muse, mutect2, varscan2
- USH1C | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs776511246, COSV50018869; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- WNT7A | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs879255548, COSV53198977; ClinVar: pathogenic; called by mutect2, varscan2
- A1CF | c.1152G>A p.M384I | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.838); catalogued as rs1250432490, COSV50959461; called by muse, varscan2
- A1CF | c.376C>T p.L126F | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.179); catalogued as COSV50967755, COSV50977725; called by muse, mutect2, varscan2
- A1CF | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV50968367; called by muse, mutect2, varscan2
- A2M | c.3931G>A p.E1311K | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV59382802; called by muse, mutect2, varscan2
- A2M | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.049); catalogued as COSV59386976; called by muse, mutect2, varscan2
- A2M | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778604418, COSV59383298; called by mutect2, varscan2
- A2ML1 | c.1913C>T p.P638L | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV55287138; called by muse, mutect2, varscan2
- AAAS | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 83/251 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52933013; called by muse, mutect2, varscan2
- AACS | c.787C>T p.L263F | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV55536853; called by muse, mutect2, varscan2
- AACS | c.1810C>T p.R604C | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs778996743, COSV55536869; called by muse, varscan2
- AADAC | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV51759404; called by muse, mutect2, varscan2
- AADACL2 | c.604-1G>A p.X202_splice | Splice Site (SNP) | VAF 26/82 reads (32%) | catalogued as COSV62930572; called by muse, mutect2, varscan2
- AADACL3 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 66/197 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV60198076; called by muse, varscan2
- AADACL4 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV66106341; called by muse, varscan2
- AADACL4 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.266); catalogued as COSV66106347; called by muse, mutect2, varscan2
- AADAT | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100528586, COSV61787249; called by muse, mutect2, varscan2
- AAK1 | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.046); catalogued as COSV65907393; called by muse, mutect2, varscan2
- AARD | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs761734653, COSV65599916; called by muse, mutect2, varscan2
- AARS1 | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV55747457; called by muse, mutect2, varscan2
- AATK | c.124C>T p.L42F | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV58688250; called by muse, mutect2, varscan2
- ABAT | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 35/372 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51623621; called by muse, mutect2
- ABCA1 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); catalogued as rs1436757527, COSV66058571; called by muse, mutect2, varscan2
- ABCA10 | c.2287C>T p.R763C | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200565917, COSV52222412; called by muse, mutect2, varscan2
- ABCA12 | c.7465C>T p.H2489Y (on ENST00000272895 / NM_173076.3; = p.H2171Y on NM_015657.3) | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.05); catalogued as COSV55959988; called by muse, mutect2, varscan2
- ABCA12 | c.7393G>A p.G2465R (on ENST00000272895 / NM_173076.3; = p.G2147R on NM_015657.3) | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55960003; called by muse, mutect2, varscan2
- ABCA12 | c.5809C>T p.L1937F (on ENST00000272895 / NM_173076.3; = p.L1619F on NM_015657.3) | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV55960018, COSV99790962; called by muse, mutect2, varscan2
- ABCA12 | c.5734C>T p.R1912C (on ENST00000272895 / NM_173076.3; = p.R1594C on NM_015657.3) | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs144770649; called by muse, mutect2, varscan2
- ABCA12 | c.4369G>A p.E1457K (on ENST00000272895 / NM_173076.3; = p.E1139K on NM_015657.3) | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.16); catalogued as rs777825870, COSV55960050; called by muse, mutect2, varscan2
- ABCA12 | c.3871C>T p.P1291S (on ENST00000272895 / NM_173076.3; = p.P973S on NM_015657.3) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.166); catalogued as COSV55960067; called by muse, mutect2, varscan2
- ABCA12 | c.2812G>A p.E938K (on ENST00000272895 / NM_173076.3; = p.E620K on NM_015657.3) | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as COSV55960086; called by muse, mutect2, varscan2
- ABCA12 | c.2315G>A p.G772E (on ENST00000272895 / NM_173076.3; = p.G454E on NM_015657.3) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV55959877; called by muse, mutect2, varscan2
- ABCA12 | c.743G>A p.R248K | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371738215, COSV55967574; called by muse, mutect2, varscan2
- ABCA12 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as rs567588953, COSV55960138, COSV99789346; called by muse, mutect2, varscan2
- ABCA13 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 78/291 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV70029615; called by muse, mutect2, varscan2
- ABCA13 | c.2900C>T p.S967L | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV101330003, COSV70029659; called by muse, mutect2, varscan2
- ABCA13 | c.3061C>T p.L1021F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV70029692; called by muse, mutect2, varscan2
- ABCA13 | c.3226C>T p.R1076C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs571269467, COSV70026080; called by mutect2, varscan2
- ABCA13 | c.9260C>T p.S3087F | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV101446958, COSV71288299; called by muse, mutect2, varscan2
- ABCA13 | c.9500G>A p.R3167Q | Missense Mutation (SNP) | VAF 93/314 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1328304614, COSV71288302; called by muse, mutect2, varscan2
- ABCA13 | c.12331G>A p.E4111K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1305308818, COSV71288312; called by muse, mutect2, varscan2
- ABCA13 | c.13211C>T p.S4404F | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV68945814; called by muse, varscan2
- ABCA13 | c.14713G>A p.E4905K | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.431); catalogued as COSV68947045; called by muse, mutect2, varscan2
- ABCA2 | c.4568C>T p.S1523F (on ENST00000614293; = p.S1493F on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.535); catalogued as COSV55801725; called by muse, mutect2, varscan2
- ABCA2 | c.3803C>T p.S1268F (on ENST00000614293; = p.S1238F on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.077); catalogued as COSV55801745; called by muse, varscan2
- ABCA3 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs865833156, COSV57053930, COSV57059845; called by muse, mutect2, varscan2
- ABCA4 | c.3736C>T p.L1246F | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); catalogued as CM129565, COSV64673750; called by muse, mutect2, varscan2
- ABCA4 | c.2815G>A p.E939K | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100933299, COSV64673757; called by muse, mutect2
- ABCA4 | c.2677G>A p.A893T | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV64673762; called by muse, mutect2, varscan2
- ABCA4 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 28/76 reads (37%) | catalogued as COSV64673772; called by muse, mutect2, varscan2
- ABCA5 | c.572T>A p.V191D | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.073); catalogued as COSV67016970; called by muse, mutect2, varscan2
- ABCA6 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52638940; called by muse, mutect2, varscan2
- ABCA6 | c.1000C>T p.L334F | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.162); catalogued as COSV52638950; called by muse, mutect2, varscan2
- ABCA6 | c.655C>T p.H219Y | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV52638962; called by mutect2, varscan2
- ABCA6 | c.61C>T p.L21F | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs866307955, COSV52638986; called by muse, mutect2, varscan2
- ABCA7 | c.2569C>T p.L857F | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54029963; called by muse, mutect2, varscan2
- ABCA7 | c.2977C>T p.L993F | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54029973; called by mutect2, varscan2
- ABCA8 | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52201868; called by muse, mutect2, varscan2
- ABCA8 | c.743G>A p.R248K | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.251); catalogued as COSV52201895; called by muse, mutect2, varscan2
- ABCA8 | c.519G>A p.W173* | Nonsense Mutation (SNP) | VAF 57/219 reads (26%) | catalogued as rs1412600751, COSV52201914; called by muse, mutect2, varscan2
- ABCA9 | c.4499+1G>A p.X1500_splice | Splice Site (SNP) | VAF 49/140 reads (35%) | catalogued as COSV60625087; called by muse, mutect2, varscan2
- ABCA9 | c.2557C>T p.R853C | Missense Mutation (SNP) | VAF 59/192 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs764738392, COSV60622460, COSV60628108; called by muse, mutect2, varscan2
- ABCA9 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV60621094; called by muse, mutect2, varscan2
- ABCB1 | c.3046C>T p.P1016S | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55952008; called by muse, mutect2, varscan2
- ABCB1 | c.2165G>A p.G722E | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55947626, COSV55952023; called by muse, mutect2, varscan2
- ABCB1 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV55952028, COSV55956902; called by muse, mutect2, varscan2
- ABCB1 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55946143; called by muse, varscan2
- ABCB1 | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55952046; called by muse, mutect2, varscan2
- ABCB1 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV55952055; called by muse, mutect2, varscan2
- ABCB11 | c.3912G>A p.M1304I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.545); catalogued as COSV55591457; called by muse, mutect2, varscan2
- ABCB11 | c.3799G>A p.G1267S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55591477; called by muse, mutect2, varscan2
- ABCB11 | c.3606G>C p.M1202I | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.238); catalogued as COSV55591493; called by muse, mutect2
- ABCB11 | c.3408G>C p.K1136N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.124); catalogued as rs759634677, COSV55591509, COSV55599727; called by muse, mutect2, varscan2
- ABCB11 | c.2824G>A p.E942K | Missense Mutation (SNP) | VAF 66/282 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55591534; called by muse, mutect2, varscan2
- ABCB11 | c.2605C>T p.Q869* | Nonsense Mutation (SNP) | VAF 31/309 reads (10%) | catalogued as COSV55591549; called by muse, mutect2
- ABCB11 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1326800279, COSV55586587; called by muse, mutect2, varscan2
- ABCB4 | c.3221G>A p.G1074E | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55935600; called by muse, mutect2, varscan2
- ABCB4 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55932472; called by muse, mutect2, varscan2
- ABCB4 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.864); catalogued as COSV55935621; called by muse, varscan2
- ABCB4 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV55933743; called by muse, varscan2
- ABCB5 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV68857449; called by muse, mutect2, varscan2
- ABCB5 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs190460902; called by muse, mutect2, varscan2
- ABCB5 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs768578610, COSV51702735, COSV51707828; called by muse, mutect2, varscan2
- ABCB5 | c.1870G>A p.D624N (on ENST00000404938 / NM_001163941.2; = p.D179N on NM_178559.6) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.139); catalogued as rs534768118, COSV51710085; called by muse, varscan2
- ABCB7 | c.1762C>T p.H588Y (on ENST00000373394 / NM_001271696.3; = p.H589Y on NM_004299.6) | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV53719724, COSV53723438; called by muse, mutect2, varscan2
- ABCB8 | c.1762G>A p.A588T (on ENST00000297504 / NM_001282291.2; = p.A571T on NM_007188.5) | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52504818; called by muse, mutect2, varscan2
- ABCC1 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1430043914, COSV60686310; called by muse, varscan2
- ABCC1 | c.2882C>T p.S961F | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV60686338; called by muse, mutect2, varscan2
- ABCC1 | c.4142C>T p.S1381L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs574461562, COSV60686353; called by muse, mutect2, varscan2
- ABCC10 | c.641C>T p.A214V (on ENST00000372530 / NM_001198934.2; = p.A171V on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV55088107; called by muse, mutect2, varscan2
- ABCC10 | c.4184C>T p.A1395V (on ENST00000372530 / NM_001198934.2; = p.A1367V on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773796273, COSV55088149; called by mutect2, varscan2
- ABCC11 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.671); catalogued as COSV62323265; called by muse, mutect2, varscan2
- ABCC12 | c.2209G>A p.V737I | Missense Mutation (SNP) | VAF 91/463 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs930851658, COSV60914113; called by muse, mutect2, varscan2
- ABCC12 | c.998G>A p.R333K | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV60911644; called by muse, mutect2, varscan2
- ABCC2 | c.1789C>T p.P597S | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV64986353; called by muse, mutect2, varscan2
- ABCC3 | c.185G>A p.G62D | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753786386, COSV53322084; called by muse, mutect2, varscan2
- ABCC3 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.039); catalogued as COSV53322133; called by muse, mutect2, varscan2
- ABCC3 | c.2096G>A p.W699* | Nonsense Mutation (SNP) | VAF 26/95 reads (27%) | catalogued as COSV53322153; called by muse, mutect2, varscan2
- ABCC3 | c.3026C>T p.S1009F | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV53316785; called by muse, varscan2
- ABCC8 | c.4435G>A p.E1479K | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as COSV56850846; called by muse, varscan2
- ABCC8 | c.3979G>A p.G1327R | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV56850855, COSV56856003, COSV56858189; called by muse, varscan2
- ABCC8 | c.1985C>T p.P662L | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV56850886; called by muse, varscan2
- ABCC8 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV56850917; called by muse, mutect2, varscan2
- ABCC9 | c.4618C>T p.L1540F | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV53977894, COSV99684155; called by muse, mutect2, varscan2
- ABCC9 | c.4061C>T p.S1354L | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53972591; called by muse, mutect2
- ABCC9 | c.1874C>T p.S625L | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs75460545, COSV53962326; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC9 | c.1724T>A p.L575Q | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53972642; called by muse, varscan2
- ABCC9 | c.1186C>T p.L396F | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53970126; called by muse, mutect2, varscan2
- ABCC9 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 24/91 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.54); catalogued as COSV53972690; called by muse, mutect2, varscan2
- ABCD2 | c.1697C>T p.S566L | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as COSV58051966; called by muse, mutect2, varscan2
- ABCD3 | c.1390C>T p.R464* | Nonsense Mutation (SNP) | VAF 14/86 reads (16%) | catalogued as rs373698570; called by muse, mutect2, varscan2
- ABCF3 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770951242, COSV53051574; called by muse, mutect2, varscan2
- ABCG1 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 48/286 reads (17%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs751587938, COSV59204556, COSV59207097; called by muse, mutect2, varscan2
- ABCG2 | c.393G>A p.M131I | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as rs759726272, COSV52946251; called by muse, mutect2, varscan2
- ABCG4 | c.748G>A p.G250S | Missense Mutation (SNP) | VAF 71/243 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1195565008, COSV56643275, COSV56643566; called by muse, mutect2, varscan2
- ABHD12 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.285); catalogued as COSV59285809; called by muse, mutect2, varscan2
- ABHD5 | c.658T>G p.F220V | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV50006571; called by muse, varscan2
- ABI3 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV56799590; called by muse, mutect2, varscan2
- ABI3BP | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751074977, COSV52536843, COSV99427604; called by muse, mutect2, varscan2
- ABI3BP | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as rs367929594; called by muse, mutect2, varscan2
- ABI3BP | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52536878; called by muse, varscan2
- ABI3BP | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV52536893; called by muse, varscan2
- ABI3BP | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753741511, COSV52536911; called by muse, mutect2, varscan2
- ABL1 | c.1043C>T p.S348L | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100584729, COSV59329606; called by mutect2, varscan2
- ABL1 | c.2945C>T p.P982L | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.243); catalogued as COSV59332127; called by muse, mutect2, varscan2
- ABLIM1 | c.2103G>A p.M701I | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as COSV53306759; called by muse, mutect2, varscan2
- ABLIM1 | c.1754G>A p.R585K | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.269); catalogued as COSV53306786; called by muse, mutect2, varscan2
- ABLIM1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as rs756279625, COSV53306820; called by muse, mutect2
- ABLIM2 | c.1380G>A p.K460= (on ENST00000341937 / NM_001130084.2; = p.K409= on NM_032432.5) | Splice Region (SNP) | VAF 14/83 reads (17%) | catalogued as rs764494318, COSV56404784, COSV99589204; called by muse, mutect2, varscan2
- ABLIM3 | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV58643476; called by muse, mutect2, varscan2
- ABO | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV71743539; called by muse, mutect2, varscan2
- ABRA | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.425); catalogued as rs368270742, COSV61732483; called by muse, mutect2, varscan2
- AC005833.1 | c.1169G>A p.G390E | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious, low confidence (0); catalogued as COSV52897571; called by muse, mutect2, varscan2
- AC005833.1 | c.1327G>A p.G443R | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious, low confidence (0); catalogued as COSV52897583; called by muse, mutect2, varscan2
- AC008397.2 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760188691, COSV53207034; called by muse, mutect2, varscan2
- AC008397.2 | c.711C>T p.F237= | Splice Region (SNP) | VAF 39/148 reads (26%) | catalogued as COSV53207056; called by muse, mutect2, varscan2
- AC008397.2 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs529117552, COSV53207072; called by muse, mutect2, varscan2
- AC008676.3 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs540171356, COSV56636734; called by muse, varscan2
- AC068580.4 | c.964C>T p.Q322* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as COSV52588247; called by muse, mutect2, varscan2
- AC090517.4 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1382450059, COSV50997111; called by muse, mutect2, varscan2
- AC092143.1 | c.2077C>T p.P693S | Missense Mutation (SNP) | VAF 56/257 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59247893; called by muse, mutect2, varscan2
- AC098582.1 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV52020408; called by muse, mutect2, varscan2
- AC100868.1 | c.1657G>A p.D553N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV51843219; called by muse, mutect2, varscan2
- AC100868.1 | c.1193A>T p.D398V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as COSV99225058; called by muse, mutect2, varscan2
- AC100868.1 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.133); catalogued as COSV99225060; called by muse, mutect2, varscan2
- AC100868.1 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.596); catalogued as COSV99225064; called by muse, mutect2, varscan2
- AC100868.1 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV99225067; called by muse, mutect2, varscan2
- AC109583.1 | c.1048C>T p.Q350* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as rs1213293947, COSV58405762; called by muse, mutect2, varscan2
- AC109583.1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 90/303 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as COSV58405767; called by muse, mutect2, varscan2
- AC109583.1 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.188); catalogued as rs745519089, COSV58405775; called by mutect2, varscan2
- AC126283.2 | c.714G>A p.M238I | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV67098718; called by muse, mutect2, varscan2
- ACACA | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs1162425599; called by muse, varscan2
- ACACB | c.5287C>T p.P1763S | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58135207; called by muse, mutect2, varscan2
- ACACB | c.5599C>T p.Q1867* | Nonsense Mutation (SNP) | VAF 58/218 reads (27%) | catalogued as COSV58135224; called by muse, mutect2, varscan2
- ACAD11 | c.1679C>T p.S560F | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV53896476; called by muse, mutect2, varscan2
- ACADSB | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs138063747; called by muse, mutect2, varscan2
- ACAN | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 88/174 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61360888; called by muse, varscan2
- ACAN | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV61360900; called by muse, varscan2
- ACAN | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200578079, COSV61358808; called by muse, mutect2, varscan2
- ACAN | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV104419329, COSV61360924; called by muse, mutect2, varscan2
- ACAN | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs773211569, COSV61360940; called by muse, mutect2, varscan2
- ACAN | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.217); catalogued as COSV61360954; called by muse, varscan2
- ACAN | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61360964; called by muse, mutect2, varscan2
- ACAN | c.2761G>A p.G921R | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100719496, COSV61361004; called by muse, mutect2
- ACAN | c.2860C>T p.L954F | Missense Mutation (SNP) | VAF 78/192 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV61361015; called by muse, varscan2
- ACAN | c.5446G>A p.V1816I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.995); catalogued as COSV61361064; called by muse, mutect2, varscan2
- ACAN | c.5783C>T p.P1928L | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); catalogued as COSV61361073; called by muse, mutect2, varscan2
- ACAN | c.6335G>A p.G2112E | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.227); catalogued as COSV61361089; called by muse, varscan2
- ACAN | c.6377C>T p.S2126F | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.103); catalogued as COSV61361099; called by muse, varscan2
- ACAN | c.6431C>T p.S2144F | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV61361110; called by muse, varscan2
- ACAN | c.6620C>T p.S2207L | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs1373291263, COSV61361120; called by muse, mutect2, varscan2
- ACBD5 | c.1051C>T p.R351C (on ENST00000375888 / NM_001352568.1; = p.R342C on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/251 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs755306488, COSV65517960; called by muse, mutect2, varscan2
- ACD | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.122); catalogued as COSV54667775; called by muse, varscan2
- ACE | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs1193074438, COSV52020755; called by muse, mutect2, varscan2
- ACE | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV52007047; called by muse, varscan2
- ACE | c.1033G>A p.G345R | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.09); catalogued as COSV52007053; called by muse, mutect2, varscan2
- ACE | c.2695C>T p.P899S | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.618); catalogued as COSV52007062; called by muse, mutect2, varscan2
- ACE | c.2911C>T p.R971W | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769406157, COSV52007089; called by muse, mutect2, varscan2
- ACE | c.3046G>A p.E1016K | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52007117; called by muse, mutect2, varscan2
- ACER1 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs373287040; called by muse, mutect2, varscan2
- ACER1 | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV56835600; called by muse, mutect2
- ACER3 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as rs782329790, COSV53598670; called by muse, varscan2
- ACHE | c.1633G>A p.D545N | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53817685; called by muse, mutect2, varscan2
- ACHE | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.983); catalogued as COSV99573661; called by muse, varscan2
- ACIN1 | c.1541C>T p.A514V | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.023); catalogued as COSV52976552; called by muse, mutect2, varscan2
- ACKR1 | c.238C>T p.L80F | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63672905; called by muse, mutect2
- ACKR3 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.864); catalogued as COSV56021852; called by muse, mutect2, varscan2
- ACMSD | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.217); catalogued as rs200534044; called by muse, mutect2, varscan2
- ACOT12 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs564306951, COSV56892647, COSV56894194; called by muse, mutect2, varscan2
- ACOT7 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 53/235 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV64111878, COSV64113569; called by muse, mutect2, varscan2
- ACOX2 | c.1179G>A p.M393I | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV57149078; called by muse, varscan2
- ACOX2 | c.161-2A>T p.X54_splice | Splice Site (SNP) | VAF 26/81 reads (32%) | catalogued as COSV57149087; called by muse, varscan2
- ACP3 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs974512425, COSV60486362; called by muse, mutect2, varscan2
- ACP7 | c.106C>T p.H36Y | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58699381; called by muse, mutect2, varscan2
- ACRBP | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV57523966; called by muse, varscan2
- ACRBP | c.199G>A p.G67S | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766923238, COSV57523978; called by muse, mutect2, varscan2
- ACSBG1 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV51906370; called by muse, mutect2, varscan2
- ACSBG1 | c.747G>A p.M249I | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as rs867273879, COSV51906381; called by muse, mutect2, varscan2
- ACSBG2 | c.1612C>T p.P538S | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV53125031; called by muse, mutect2, varscan2
- ACSL3 | c.2041C>T p.R681C | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs776538313, COSV62481117; called by muse, mutect2, varscan2
- ACSL5 | c.110C>T p.P37L (on ENST00000354273; = p.P93L on NM_016234.3) | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs1428256415, COSV61130832; called by muse, varscan2
- ACSL5 | c.1468G>A p.E490K (on ENST00000354273; = p.E546K on NM_016234.3) | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.147); catalogued as rs867135949, COSV61129188; called by muse, mutect2, varscan2
- ACSM1 | c.1708C>T p.R570W | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs552842757, COSV54633124; called by muse, varscan2
- ACSM1 | c.15G>A p.M5I | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV54636101; called by muse, varscan2
- ACSM2A | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV54584924; called by muse, mutect2, varscan2
- ACSM2A | c.481G>A p.D161N (on ENST00000219054; = p.D82N on NM_001308169.2) | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs759558004, COSV54584023; called by muse, mutect2, varscan2
- ACSM2A | c.928G>A p.G310S (on ENST00000219054; = p.G231S on NM_001308169.2) | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.035); catalogued as COSV54584961; called by muse, mutect2, varscan2
- ACSM2A | c.1128G>A p.M376I (on ENST00000219054; = p.M297I on NM_001308169.2) | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as COSV54584974; called by muse, varscan2
- ACSM2A | c.1449G>A p.M483I (on ENST00000219054; = p.M404I on NM_001308169.2) | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs867951473, COSV54585011; called by muse, varscan2
- ACSM2A | c.1501C>T p.R501* (on ENST00000219054; = p.R422* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 14/58 reads (24%) | catalogued as rs376967417, COSV54582297; called by muse, varscan2
- ACSM2A | c.1679G>A p.R560Q (on ENST00000219054; = p.R481Q on NM_001308169.2) | Missense Mutation (SNP) | VAF 60/261 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148142047; called by muse, varscan2
- ACSM2B | c.1403C>T p.S468F | Missense Mutation (SNP) | VAF 76/524 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61657846, COSV61657963; called by muse, varscan2
- ACSM2B | c.1049G>A p.R350K | Missense Mutation (SNP) | VAF 47/263 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777315522, COSV61657970; called by muse, mutect2, varscan2
- ACSM2B | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.244); catalogued as rs768259198, COSV61657972, COSV61659581; called by muse, varscan2
- ACSM2B | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100312220; called by muse, varscan2
- ACSM2B | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.715); catalogued as COSV61657974; called by muse, mutect2, varscan2
- ACSM3 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.374); catalogued as COSV55501554, COSV55502975; called by muse, mutect2, varscan2
- ACSM5 | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.384); catalogued as rs1396323862, COSV59371665; called by muse, varscan2
- ACSM6 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV58978623; called by muse, varscan2
- ACSM6 | c.765G>A p.M255I | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV58978651; called by muse, varscan2
- ACSS3 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54091525; called by muse, mutect2, varscan2
- ACSS3 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1049494749, COSV54091536; called by muse, mutect2, varscan2
- ACSS3 | c.1730C>T p.S577F | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV54091558; called by muse, varscan2
- ACSS3 | c.1775C>T p.P592L | Missense Mutation (SNP) | VAF 60/306 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as rs1171113256, COSV54091572; called by muse, varscan2
- ACSS3 | c.1900C>T p.R634* | Nonsense Mutation (SNP) | VAF 22/120 reads (18%) | catalogued as rs776097345, COSV54091174; called by muse, mutect2, varscan2
- ACSS3 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV54091590; called by muse, varscan2
- ACTA1 | c.446G>A p.R149K | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as rs398123564, CM095290, COSV64203410; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTA1 | c.203C>T p.T68I | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.565); catalogued as CM042277, CM095273, COSV100796689; called by muse, mutect2, varscan2
- ACTA2 | c.1073G>A p.W358* | Nonsense Mutation (SNP) | VAF 11/173 reads (6%) | catalogued as COSV56516667; called by muse, mutect2
- ACTB | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.874); catalogued as COSV59318728; called by muse, mutect2, varscan2
- ACTC1 | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.987); catalogued as CM086759, COSV51759217; called by muse, mutect2, varscan2
- ACTG2 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV61827917; called by muse, mutect2, varscan2
- ACTL6B | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV50515066; called by muse, varscan2
- ACTL7A | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as COSV61776275; called by muse, mutect2, varscan2
- ACTL7A | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as COSV61776734; called by muse, mutect2, varscan2
- ACTL7B | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as COSV65927391; called by muse, mutect2, varscan2
- ACTL7B | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65927396; called by muse, mutect2, varscan2
- ACTL8 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as rs886522728, COSV64861479, COSV64862066; called by muse, mutect2, varscan2
- ACTL8 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as COSV64861483; called by muse, mutect2, varscan2
- ACTL8 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs267598220, COSV64861450; called by muse, mutect2, varscan2
- ACTL8 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV100958465; called by muse, mutect2, varscan2
- ACTL9 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV61005817; called by muse, mutect2, varscan2
- ACTL9 | c.461G>A p.S154N | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); catalogued as COSV61005827; called by muse, mutect2, varscan2
- ACTN2 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1342620732, COSV63975109; called by muse, mutect2, varscan2
- ACTN2 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 57/220 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779109533, COSV63975111; ClinVar: uncertain significance; called by muse, varscan2
- ACTN2 | c.2654C>T p.S885F | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63975123; called by muse, varscan2
- ACTN2 | c.2677G>A p.D893N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs142646143, COSV63971914; ClinVar: likely benign / uncertain significance; called by muse, varscan2
- ACTR1A | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV64023342; called by muse, mutect2, varscan2
- ACTR1B | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV100007909; called by muse, mutect2, varscan2
- ACTR2 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV53201121; called by muse, mutect2, varscan2
- ACTR3B | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 73/212 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs769042294, COSV55449299; called by muse, mutect2, varscan2
- ACTR5 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as rs750748281, COSV54760781; called by muse, mutect2, varscan2
- ACTR8 | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV51636571; called by muse, mutect2, varscan2
- ACTRT1 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 140/247 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV64419460, COSV64420243; called by muse, mutect2, varscan2
- ACTRT1 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64419361; called by muse, mutect2, varscan2
- ACTRT2 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV65759430; called by muse, mutect2, varscan2
- ACTRT2 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.197); catalogued as COSV65759436; called by muse, mutect2, varscan2
- ACVR1B | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 17/134 reads (13%) | catalogued as COSV57777317; called by muse, mutect2, varscan2
- ACVR1C | c.1280C>T p.S427L | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1329691825, COSV54646375; called by muse, mutect2, varscan2
- ACVRL1 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66360256; called by muse, mutect2, varscan2
- ACY3 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs202084142, COSV54828833; called by muse, mutect2, varscan2
- ADAD1 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs770989160, COSV56641414; called by muse, mutect2, varscan2
- ADAD1 | c.147G>A p.M49I | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV56643729; called by muse, mutect2, varscan2
- ADAD1 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.177); catalogued as rs867796878, COSV56641957; called by muse, mutect2, varscan2
- ADAD1 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.268); catalogued as COSV56643740; called by muse, mutect2
- ADAD2 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as rs759599115, COSV51893492; called by muse, mutect2, varscan2
- ADAD2 | c.430C>T p.P144S (on ENST00000315906 / NM_001145400.2; = p.P216S on NM_139174.4) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as COSV51893502; called by muse, mutect2, varscan2
- ADAL | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.119); catalogued as COSV67500556; called by muse, mutect2, varscan2
- ADAM18 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.142); catalogued as COSV55847809; called by muse, mutect2, varscan2
- ADAM18 | c.664T>C p.F222L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV55851387; called by muse, varscan2
- ADAM18 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.965); catalogued as COSV55847819; called by muse, mutect2
- ADAM18 | c.1397G>A p.G466E | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55847827; called by muse, mutect2, varscan2
- ADAM18 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV55847835; called by muse, mutect2, varscan2
- ADAM18 | c.1976C>T p.S659F | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as rs773233943, COSV55847843; called by mutect2, varscan2
- ADAM18 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55847852; called by muse, mutect2, varscan2
- ADAM19 | c.2245C>T p.P749S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.253); catalogued as COSV57430458; called by muse, mutect2, varscan2
- ADAM19 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.574); catalogued as COSV57430482; called by muse, varscan2
- ADAM19 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV57430543; called by muse, mutect2, varscan2
- ADAM2 | c.1939C>T p.Q647* | Nonsense Mutation (SNP) | VAF 41/176 reads (23%) | catalogued as rs868202213, COSV55862421, COSV55864717; called by muse, mutect2, varscan2
- ADAM2 | c.1790C>T p.S597L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs775795284, COSV55860692; called by muse, mutect2, varscan2
- ADAM2 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55858944; called by muse, varscan2
- ADAM2 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55862444; called by muse, varscan2
- ADAM2 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs774068680, COSV55862454, COSV55866813; called by mutect2, varscan2
- ADAM2 | c.506G>A p.S169N | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV55862464; called by muse, mutect2, varscan2
- ADAM20 | c.199T>C p.F67L | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV56455060; called by muse, mutect2, varscan2
- ADAM21 | c.2042G>A p.G681E | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50794344; called by muse, mutect2, varscan2
- ADAM22 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs535039786, COSV55969346; called by muse, mutect2, varscan2
- ADAM22 | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV55977446; called by muse, varscan2
- ADAM22 | c.1244C>T p.T415I | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV55977477; called by muse, varscan2
- ADAM23 | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as COSV52214804, COSV52216093; called by muse, mutect2, varscan2
- ADAM28 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.026); catalogued as COSV56100792; called by muse, mutect2, varscan2
- ADAM28 | c.513G>A p.M171I | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV56100818; called by muse, varscan2
- ADAM28 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56100844; called by muse, varscan2
- ADAM28 | c.2190G>A p.M730I | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV56100893; called by muse, mutect2, varscan2
- ADAM29 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.91); PolyPhen benign (0.011); catalogued as COSV100821876; called by muse, mutect2, varscan2
- ADAM29 | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63663801; called by muse, varscan2
- ADAM29 | c.957G>A p.M319I | Missense Mutation (SNP) | VAF 72/268 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as COSV63663814; called by muse, mutect2, varscan2
- ADAM29 | c.1075G>A p.G359S | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated (0.99); PolyPhen benign (0.009); catalogued as COSV63663820; called by muse, mutect2, varscan2
- ADAM29 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.248); catalogued as rs867333516, COSV100822036, COSV63663831; called by muse, varscan2
- ADAM29 | c.1319G>A p.G440E | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63663837; called by muse, varscan2
- ADAM29 | c.1814G>A p.G605E | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV63663841; called by muse, mutect2, varscan2
- ADAM30 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV65561140; called by muse, mutect2, varscan2
- ADAM30 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV65561154; called by muse, mutect2, varscan2
- ADAM32 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.25); catalogued as rs750544835, COSV65949503; called by muse, mutect2, varscan2
- ADAM32 | c.1135C>T p.L379F | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1302225465, COSV65949510; called by muse, mutect2
- ADAM32 | c.1627G>A p.G543R | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.222); catalogued as COSV65949517; called by muse, mutect2, varscan2
- ADAM32 | c.1976G>A p.G659E | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.38); catalogued as rs766436330, COSV65947294; called by muse, mutect2, varscan2
- ADAM33 | c.333G>A p.T111= | Splice Region (SNP) | VAF 6/42 reads (14%) | catalogued as rs371142706, COSV62934864; called by mutect2, varscan2
- ADAM7 | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV51540315; called by muse, varscan2
- ADAMDEC1 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs778034086, COSV56475312; called by muse, mutect2, varscan2
- ADAMDEC1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.904); catalogued as rs760760973, COSV56474739; called by muse, mutect2, varscan2
- ADAMDEC1 | c.878G>A p.W293* | Nonsense Mutation (SNP) | VAF 16/62 reads (26%) | catalogued as COSV56475352; called by muse, varscan2
- ADAMTS10 | c.2624G>A p.R875K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV54354425; called by muse, mutect2, varscan2
- ADAMTS10 | c.2248G>A p.G750R | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); catalogued as COSV54355103; called by muse, mutect2, varscan2
- ADAMTS10 | c.2152G>A p.G718R | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.603); catalogued as rs1555738079, COSV54355114; called by muse, mutect2, varscan2
- ADAMTS10 | c.1679G>A p.S560N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV54355130; called by muse, mutect2, varscan2
- ADAMTS10 | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs782693285, COSV54355156; called by muse, varscan2
- ADAMTS12 | c.4162G>A p.E1388K | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as rs1229940482, COSV61263481; called by muse, mutect2, varscan2
- ADAMTS12 | c.3748C>T p.P1250S | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV61263487; called by muse, mutect2, varscan2
- ADAMTS12 | c.2138G>A p.G713E | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV61263490, COSV61272426; called by muse, mutect2, varscan2
- ADAMTS14 | c.1748C>T p.S583F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs777350272, COSV64602235; called by muse, mutect2, varscan2
- ADAMTS14 | c.3527C>T p.S1176F | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as rs749121878, COSV64602314; called by muse, mutect2, varscan2
- ADAMTS15 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV54505744; called by muse, varscan2
- ADAMTS15 | c.1978G>A p.D660N | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV54505769; called by muse, mutect2, varscan2
- ADAMTS16 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.112); catalogued as rs369076448; called by muse, varscan2
- ADAMTS16 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs767751970, COSV56990630; called by muse, varscan2
- ADAMTS16 | c.2251C>T p.L751F | Missense Mutation (SNP) | VAF 41/202 reads (20%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.522); catalogued as COSV56990648; called by muse, mutect2, varscan2
- ADAMTS16 | c.2395G>A p.G799R | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56990673; called by muse, mutect2, varscan2
- ADAMTS18 | c.3079C>T p.P1027S | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.934); catalogued as rs1269411432, COSV51411068; called by muse, mutect2, varscan2
- ADAMTS18 | c.2447G>A p.G816E | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV51411130, COSV51424470; called by muse, varscan2
- ADAMTS18 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.63); catalogued as COSV51411292; called by muse, mutect2, varscan2
- ADAMTS18 | c.1805C>T p.S602F | Missense Mutation (SNP) | VAF 86/277 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51411353; called by muse, mutect2, varscan2
- ADAMTS18 | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.456); catalogued as rs767415259, COSV51411403; called by muse, mutect2, varscan2
- ADAMTS18 | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.029); catalogued as rs149929752, COSV51405141; called by muse, mutect2, varscan2
- ADAMTS18 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs146432168; called by muse, varscan2
- ADAMTS18 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.566); catalogued as rs1251634347, COSV51411668; called by muse, varscan2
- ADAMTS18 | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0.048); catalogued as rs1245487308, COSV51411727; ClinVar: uncertain significance; called by muse, varscan2
- ADAMTS18 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 53/374 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1206732643, COSV51404362, COSV51405391; called by muse, mutect2, varscan2
- ADAMTS19 | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.059); catalogued as rs760704814, COSV50749242; called by muse, mutect2, varscan2
- ADAMTS19 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50749277; called by muse, varscan2
- ADAMTS19 | c.2251G>A p.G751R | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50749336; called by muse, mutect2, varscan2
- ADAMTS19 | c.3181G>A p.G1061S | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV50749426; called by muse, varscan2
- ADAMTS2 | c.2644C>T p.R882C | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760662401, COSV52375836; called by muse, mutect2, varscan2
- ADAMTS2 | c.2460C>T p.V820= | Splice Region (SNP) | VAF 16/66 reads (24%) | catalogued as rs1561768910, COSV52375869; called by muse, varscan2
- ADAMTS2 | c.2434C>T p.L812F | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52375879; called by muse, varscan2
- ADAMTS2 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); catalogued as COSV52375890; called by muse, varscan2
- ADAMTS2 | c.2029G>A p.G677R | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52375900, COSV52397019; called by muse, varscan2
- ADAMTS20 | c.5506G>A p.G1836R | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67131860; called by muse, mutect2
- ADAMTS20 | c.4922C>T p.P1641L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.16); catalogued as rs1204685543, COSV67131866; called by muse, varscan2
- ADAMTS20 | c.4000G>A p.E1334K | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.169); catalogued as COSV101166259, COSV67131877; called by muse, varscan2
- ADAMTS20 | c.3013G>A p.E1005K | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0.065); catalogued as COSV67131879; called by muse, varscan2
- ADAMTS20 | c.2956G>A p.E986K | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.373); catalogued as COSV67130927, COSV67131880; called by muse, varscan2
- ADAMTS20 | c.1724G>A p.G575E | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1166581411, COSV101238748; called by muse, mutect2
- ADAMTS20 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV67131883; called by muse, mutect2, varscan2
- ADAMTS20 | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV67131884; called by muse, mutect2, varscan2
- ADAMTS20 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.557); catalogued as COSV67130784; called by muse, mutect2, varscan2
- ADAMTS3 | c.3413G>A p.G1138E | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs1346342321, COSV54392001; called by muse, mutect2, varscan2
- ADAMTS3 | c.2617C>T p.R873C | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759621311, COSV54392009; called by muse, mutect2, varscan2
- ADAMTS3 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV54392030; called by muse, mutect2, varscan2
- ADAMTS5 | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 48/72 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53179331; called by muse, mutect2, varscan2
- ADAMTS5 | c.1732C>T p.Q578* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV53179343; called by muse, mutect2, varscan2
- ADAMTS6 | c.3163G>A p.D1055N | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.213); catalogued as COSV58681720; called by muse, varscan2
- ADAMTS6 | c.3158C>T p.S1053F | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58683111; called by muse, varscan2
- ADAMTS6 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0.363); catalogued as rs574046720, COSV58681823; called by muse, varscan2
- ADAMTS6 | c.2728G>A p.E910K | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.542); catalogued as COSV58683141; called by muse, varscan2
- ADAMTS6 | c.1370+1G>A p.X457_splice | Splice Site (SNP) | VAF 26/87 reads (30%) | catalogued as COSV66859917; called by muse, mutect2, varscan2
- ADAMTS6 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66859927; called by muse, mutect2, varscan2
- ADAMTS7 | c.4093C>T p.P1365S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs529016137, COSV66307370; called by muse, varscan2
- ADAMTS7 | c.2587C>T p.P863S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.41); catalogued as COSV66307376; called by muse, mutect2, varscan2
- ADAMTS7 | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs148218299; called by muse, mutect2, varscan2
- ADAMTS7 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.396); catalogued as COSV66307392; called by muse, varscan2
- ADAMTS8 | c.2457C>A p.S819R | Missense Mutation (SNP) | VAF 66/276 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV57293451; called by muse, varscan2
- ADAMTS8 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 81/272 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57293549; called by muse, mutect2, varscan2
- ADAMTS9 | c.5420G>A p.G1807E | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868429914, COSV55781433; called by muse, mutect2, varscan2
- ADAMTS9 | c.5292G>A p.K1764= | Splice Region (SNP) | VAF 37/154 reads (24%) | catalogued as COSV55781446; called by muse, varscan2
- ADAMTS9 | c.5276G>A p.R1759K | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141560382, COSV55781458; called by muse, varscan2
- ADAMTS9 | c.3503C>T p.P1168L | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs202038398, COSV55781490; called by muse, mutect2, varscan2
- ADAMTS9 | c.2699G>A p.R900Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs766944266, COSV55777384; called by muse, varscan2
- ADAMTS9 | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1460189930, COSV55781507; called by muse, mutect2, varscan2
- ADAMTS9 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55781520, COSV99898817; called by muse, varscan2
- ADAMTSL1 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs750369044, COSV65892513; called by muse, varscan2
- ADAMTSL1 | c.2189C>T p.P730L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs563470348, COSV65892516; called by muse, varscan2
- ADAMTSL1 | c.2380C>T p.L794F | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.711); catalogued as rs1311818681; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2740G>A p.D914N | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs1431878044, COSV65892525; called by muse, varscan2
- ADAMTSL1 | c.2819C>T p.S940L | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.59); catalogued as rs1340218977, COSV65892530; called by muse, varscan2
- ADAMTSL1 | c.4525C>T p.Q1509* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | catalogued as COSV65877941; called by muse, mutect2
- ADAMTSL2 | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as rs1233835454, COSV63203957; called by muse, varscan2
- ADAMTSL3 | c.548G>A p.G183E | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54440919; called by muse, mutect2, varscan2
- ADAMTSL3 | c.728G>A p.R243K | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV54448802; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1024C>T p.Q342* | Nonsense Mutation (SNP) | VAF 13/66 reads (20%) | catalogued as COSV54448813; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV54448826; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2111C>T p.P704L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV54448837; called by muse, mutect2
- ADAMTSL3 | c.3203G>A p.G1068E | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54448848; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3458G>T p.G1153V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.274); catalogued as COSV54448865; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4034C>T p.S1345F | Missense Mutation (SNP) | VAF 63/260 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.011); catalogued as COSV54439543, COSV54448884; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4274-1G>A p.X1425_splice | Splice Site (SNP) | VAF 15/251 reads (6%) | catalogued as COSV54448892, COSV54451841; called by muse, mutect2
- ADAMTSL4 | c.2104G>A p.E702K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV54999942; called by muse, mutect2
- ADAP1 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV56213606; called by muse, mutect2, varscan2
- ADAP1 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.807); catalogued as rs761464767, COSV56213625; called by muse, mutect2, varscan2
- ADAR | c.2299C>T p.R767C | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs1266840077, COSV52713140; called by muse, mutect2, varscan2
- ADCK1 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as rs779266129, COSV53081154; called by muse, mutect2, varscan2
- ADCY1 | c.2725G>A p.E909K | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.052); catalogued as COSV52034987; called by muse, mutect2, varscan2
- ADCY10 | c.3676C>T p.H1226Y | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV63240983; called by muse, mutect2, varscan2
- ADCY10 | c.2920C>T p.P974S | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.311); catalogued as rs777782090, COSV63239033; called by muse, mutect2, varscan2
- ADCY10 | c.2275G>A p.E759K | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs1344282343, COSV63239754; called by muse, mutect2, varscan2
- ADCY10 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV63240994; called by mutect2, varscan2
- ADCY10 | c.733C>A p.H245N | Missense Mutation (SNP) | VAF 114/385 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV63240998; called by muse, mutect2, varscan2
- ADCY3 | c.1676C>T p.S559L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.184); catalogued as COSV99567519; called by muse, varscan2
- ADCY5 | c.2317C>T p.L773F | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV59198292; called by muse, mutect2
- ADCY5 | c.2164C>T p.R722C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as rs1412031145, COSV59194201; called by muse, mutect2, varscan2
- ADCY7 | c.979G>A p.G327S | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1490845044, COSV54266995, COSV99576180; called by muse, mutect2, varscan2
- ADCY8 | c.3605C>T p.S1202F | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV53908764; called by muse, mutect2, varscan2
- ADCY8 | c.2672G>A p.G891E | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV53908788; called by muse, mutect2, varscan2
- ADCY8 | c.2502+1G>A p.X834_splice | Splice Site (SNP) | VAF 13/34 reads (38%) | catalogued as COSV53908801; called by muse, mutect2, varscan2
- ADCY8 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 89/260 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53908821; called by muse, varscan2
- ADCY8 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.963); catalogued as rs1563724934, COSV53903301, COSV99651047; called by muse, varscan2
- ADCYAP1R1 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1321839365, COSV100416412, COSV58443767; called by muse, mutect2, varscan2
- ADD2 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV52459970; called by muse, mutect2, varscan2
- ADD2 | c.1427C>T p.P476L | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs781951897, COSV52461404; called by muse, mutect2
- ADD2 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV100034486; called by muse, mutect2, varscan2
- ADD2 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV52461426; called by muse, mutect2, varscan2
- ADD2 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52454309; called by muse, varscan2
- ADD2 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as rs782440062, COSV52461480; called by muse, mutect2, varscan2
- ADD3 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV53322479; called by muse, mutect2, varscan2
- ADGRA1 | c.1244C>T p.T415I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV63416589; called by muse, varscan2
- ADGRA3 | c.3487C>T p.R1163* | Nonsense Mutation (SNP) | VAF 28/89 reads (31%) | catalogued as COSV51562452; called by muse, mutect2, varscan2
- ADGRB1 | c.2116C>T p.P706S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs1260265786, COSV60096936; called by muse, mutect2, varscan2
- ADGRB2 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV57073790; called by muse, mutect2
- ADGRB3 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1477081846, COSV65396572; called by muse, mutect2, varscan2
- ADGRB3 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs766735540, COSV65381042; called by muse, mutect2, varscan2
- ADGRB3 | c.2166G>A p.M722I | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV65396588, COSV65401961; called by muse, varscan2
- ADGRB3 | c.3410C>T p.S1137L | Missense Mutation (SNP) | VAF 76/208 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV53245614; called by muse, mutect2, varscan2
- ADGRB3 | c.3521C>T p.S1174L | Missense Mutation (SNP) | VAF 71/154 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs865786073, COSV53245625; called by muse, mutect2, varscan2
- ADGRD1 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.138); catalogued as COSV55445873; called by muse, mutect2, varscan2
- ADGRE1 | c.116C>T p.T39I | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV51675810, COSV51678056; called by muse, varscan2
- ADGRE1 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.111); catalogued as rs767902336, COSV51675820; called by muse, mutect2
- ADGRE1 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.874); catalogued as rs868154768, COSV51675842; called by muse, varscan2
- ADGRE1 | c.1450G>T p.V484L | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV51675855; called by muse, mutect2, varscan2
- ADGRE3 | c.1259C>T p.S420F | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53735839; called by muse, mutect2
- ADGRE3 | c.1219C>T p.L407F | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53730756; called by muse, mutect2, varscan2
- ADGRE3 | c.447G>A p.W149* | Nonsense Mutation (SNP) | VAF 14/120 reads (12%) | catalogued as rs751214497, COSV53730767; called by mutect2, varscan2
- ADGRE5 | c.1172C>T p.A391V (on ENST00000242786 / NM_078481.4; = p.A298V on NM_001784.5) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs769484947, COSV54408401; called by mutect2, varscan2
- ADGRF1 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as rs749470869, COSV51945682; called by muse, mutect2, varscan2
- ADGRF3 | c.963G>A p.W321* (on ENST00000311519 / NM_001145168.1; = p.W122* on NM_153835.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV61048855; called by muse, mutect2, varscan2
- ADGRF4 | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.185); catalogued as rs1296218344, COSV51952537; called by muse, mutect2
- ADGRF4 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.021); catalogued as COSV51950717; called by muse, mutect2, varscan2
- ADGRF4 | c.1070G>A p.R357K | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.338); catalogued as rs1561868800, COSV51952604; called by muse, mutect2, varscan2
- ADGRF5 | c.3725G>A p.G1242E | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.618); catalogued as rs761917667, COSV51934185; called by muse, varscan2
- ADGRF5 | c.3688C>T p.L1230F | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51934196, COSV99346363; called by muse, varscan2
- ADGRF5 | c.2527C>T p.P843S | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV51934217, COSV51937653; called by muse, mutect2, varscan2
- ADGRF5 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1288656144, COSV51934228; called by muse, mutect2, varscan2
- ADGRG3 | c.1471G>A p.G491R | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100341977; called by muse, mutect2, varscan2
- ADGRG3 | c.1472G>A p.G491E | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100341980; called by muse, mutect2, varscan2
- ADGRG4 | c.1166C>T p.S389L | Missense Mutation (SNP) | VAF 53/87 reads (61%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV54950988; called by muse, mutect2, varscan2
- ADGRG4 | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV54956534; called by muse, mutect2, varscan2
- ADGRG4 | c.3029C>T p.P1010L | Missense Mutation (SNP) | VAF 77/131 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54956566; called by muse, mutect2, varscan2
- ADGRG4 | c.4899G>A p.M1633I | Missense Mutation (SNP) | VAF 68/123 reads (55%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV54956597; called by muse, mutect2, varscan2
- ADGRG4 | c.5255C>T p.S1752L | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as COSV54956610; called by muse, mutect2, varscan2
- ADGRG4 | c.5821C>T p.P1941S | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54956621, COSV99796976; called by muse, mutect2, varscan2
- ADGRG4 | c.7052G>A p.S2351N | Missense Mutation (SNP) | VAF 74/118 reads (63%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1213428215, COSV54956630; called by muse, mutect2, varscan2
- ADGRG4 | c.8315G>A p.R2772Q | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs781632638, COSV54953743, COSV54956645; called by muse, mutect2, varscan2
- ADGRG5 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61083414; called by muse, mutect2, varscan2
- ADGRG6 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV51592607; called by muse, mutect2, varscan2
- ADGRG7 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV56293914; called by muse, mutect2
- ADGRG7 | c.1979+1G>A p.X660_splice | Splice Site (SNP) | VAF 18/66 reads (27%) | catalogued as rs771501907, COSV56296910; called by muse, mutect2, varscan2
- ADGRL2 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as COSV54652616, COSV54656845; called by muse, mutect2, varscan2
- ADGRL2 | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as COSV99586805; called by muse, mutect2, varscan2
- ADGRL2 | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs758607216, COSV99586809; called by muse, mutect2, varscan2
- ADGRL2 | c.1963C>T p.L655F (on ENST00000370717 / NM_001366005.1; = p.L642F on NM_012302.4) | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV54668072; called by muse, mutect2, varscan2
- ADGRL3 | c.1586G>A p.G529E (on ENST00000506720 / NM_001322402.2; = p.G461E on NM_015236.6) | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV72230634; called by muse, mutect2, varscan2
- ADGRL3 | c.3685C>T p.R1229* (on ENST00000506720 / NM_001322402.2; = p.R1161* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 33/108 reads (31%) | catalogued as rs1170856272, COSV72230635; called by muse, mutect2, varscan2
- ADGRL4 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as COSV66061774; called by muse, varscan2
- ADGRV1 | c.1560T>G p.F520L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.817); catalogued as COSV67985644; called by muse, varscan2
- ADGRV1 | c.1688G>A p.G563E | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV67985649; called by muse, mutect2, varscan2
- ADGRV1 | c.2408G>A p.G803E | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67985652; called by muse, varscan2
- ADGRV1 | c.2905G>A p.E969K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67985660; called by muse, mutect2, varscan2
- ADGRV1 | c.3106G>A p.V1036I | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV67985664; called by muse, mutect2, varscan2
- ADGRV1 | c.3417G>A p.W1139* | Nonsense Mutation (SNP) | VAF 44/163 reads (27%) | catalogued as COSV67985669; called by muse, mutect2, varscan2
- ADGRV1 | c.4016C>T p.T1339I | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as COSV67985674; called by muse, varscan2
- ADGRV1 | c.4876G>A p.D1626N | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67985687; called by muse, mutect2, varscan2
- ADGRV1 | c.5182C>T p.P1728S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV67985690; called by muse, mutect2, varscan2
- ADGRV1 | c.6058G>A p.D2020N | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.167); catalogued as COSV67979774; called by muse, mutect2, varscan2
- ADGRV1 | c.6647G>A p.G2216E | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67985695, COSV67989518; called by muse, mutect2, varscan2
- ADGRV1 | c.8197C>T p.R2733* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as rs1463244885, COSV67977926; called by muse, mutect2, varscan2
- ADGRV1 | c.9130C>T p.Q3044* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as rs1282761845, COSV67983279, COSV67985701; called by muse, mutect2
- ADGRV1 | c.9236A>C p.N3079T | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV67985705; called by muse, mutect2
- ADGRV1 | c.9680G>A p.R3227Q | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs371542701, COSV101316731; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRV1 | c.9863C>T p.S3288F | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV67985716; called by muse, mutect2, varscan2
- ADGRV1 | c.10390G>A p.D3464N | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV67985718; called by muse, mutect2, varscan2
- ADGRV1 | c.10432C>T p.Q3478* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV67985722; called by muse, mutect2, varscan2
- ADGRV1 | c.11318C>A p.P3773H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67985724; called by muse, mutect2
- ADGRV1 | c.11587C>T p.L3863F | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV67978528; called by muse, mutect2, varscan2
- ADGRV1 | c.13159C>T p.R4387C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as rs770485484, COSV67985727; called by muse, mutect2, varscan2
- ADGRV1 | c.13643G>A p.G4548E | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV67985731; called by muse, mutect2, varscan2
- ADGRV1 | c.14089C>T p.L4697F | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.391); catalogued as COSV67985735; called by muse, mutect2, varscan2
- ADGRV1 | c.18055G>A p.G6019R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67985742; called by muse, varscan2
- ADGRV1 | c.18842G>A p.G6281D | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV67985750; called by muse, varscan2
- ADH1A | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1268425754, COSV52924241; called by muse, mutect2, varscan2
- ADH1C | c.945G>A p.W315* | Nonsense Mutation (SNP) | VAF 74/295 reads (25%) | catalogued as COSV72463473; called by muse, varscan2
- ADH1C | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72463474; called by muse, mutect2, varscan2
- ADH1C | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72463475; called by muse, mutect2, varscan2
- ADH6 | c.1089G>A p.M363I | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as COSV52956264; called by muse, mutect2, varscan2
- ADH6 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 42/342 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV52956275; called by mutect2, varscan2
- ADH6 | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.036); catalogued as COSV52956288; called by muse, varscan2
- ADH6 | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1235324687, COSV52956306; called by muse, varscan2
- ADH7 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52920943; called by muse, varscan2
- ADH7 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52920957; called by muse, varscan2
- ADIPOR1 | c.565C>T p.L189F | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV61851585; called by muse, mutect2
- ADM2 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as rs775358101, COSV99326629; called by mutect2, varscan2
- ADNP | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV62425433; called by muse, mutect2, varscan2
- ADORA1 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55142589; called by muse, mutect2, varscan2
- ADPRH | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV63695035; called by muse, varscan2
- ADRA1B | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.627); catalogued as COSV60701866; called by muse, mutect2, varscan2
- ADRA1D | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.374); catalogued as rs1162317844, COSV65240932; called by muse, varscan2
- ADRA2A | c.1206G>A p.W402* | Nonsense Mutation (SNP) | VAF 30/112 reads (27%) | catalogued as COSV54528098; called by muse, varscan2
- ADRA2A | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV54528112; called by muse, varscan2
- ADRA2B | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs371217738, COSV101337372; called by mutect2, varscan2
- ADRA2C | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.778); catalogued as COSV57466682; called by muse, mutect2, varscan2
- ADRB1 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65167863; called by muse, mutect2, varscan2
- ADSL | c.322C>T p.L108F | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs905003988, COSV99341923, COSV99342635; called by muse, mutect2, varscan2
- ADSL | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV50652351; called by muse, mutect2, varscan2
- AEBP1 | c.2032C>T p.Q678* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as rs1562688185, COSV56258076; called by muse, mutect2, varscan2
- AFAP1 | c.2003C>T p.S668F | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100631480, COSV61795722; called by muse, mutect2, varscan2
- AFAP1L1 | c.2264G>C p.R755T | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as COSV99695561; called by muse, mutect2, varscan2
- AFAP1L2 | c.2431-1G>A p.X811_splice (on ENST00000304129 / NM_001351075.1; = p.X807_splice on NM_032550.3 and 11 other RefSeq transcripts) | Splice Site (SNP) | VAF 26/310 reads (8%) | catalogued as COSV100412096; called by muse, mutect2
- AFAP1L2 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.864); catalogued as rs887113324, COSV58414402; called by muse, mutect2, varscan2
- AFDN | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 107/232 reads (46%) | catalogued as rs778113186, COSV60038899; called by muse, mutect2, varscan2
- AFDN | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as COSV60045298; called by muse, mutect2, varscan2
- AFDN | c.4520C>T p.S1507L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); catalogued as rs796364513, COSV60045318; called by muse, mutect2, varscan2
- AFF2 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 108/168 reads (64%) | SIFT tolerated (0.29); PolyPhen benign (0.294); catalogued as COSV60665751; called by muse, mutect2, varscan2
- AFF2 | c.2338C>T p.P780S | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.818); catalogued as COSV53990378; called by muse, mutect2, varscan2
- AFF2 | c.3398T>A p.L1133H | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53990408; called by muse, mutect2, varscan2
- AFF3 | c.707G>A p.R236K | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57855190; called by muse, mutect2, varscan2
- AFF3 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV57855204; called by muse, varscan2
- AFF4 | c.1919C>T p.S640L | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54794872; called by muse, mutect2, varscan2
- AFM | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.054); catalogued as rs766338035, COSV56920226; called by muse, mutect2, varscan2
- AFP | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs754454295, COSV56925328; called by muse, mutect2, varscan2
- AGA | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.711); catalogued as COSV99219336; called by muse, mutect2, varscan2
- AGAP1 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745864019, COSV58326610; called by muse, mutect2, varscan2
- AGAP2 | c.1001G>A p.G334E | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57728240; called by muse, mutect2, varscan2
- AGAP3 | c.1732C>T p.L578F (on ENST00000622464; = p.L614F on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.888); catalogued as COSV68244760; called by muse, mutect2
- AGAP6 | c.271C>T p.Q91* (on ENST00000374056 / NM_001365867.1; = p.Q114* on NM_001077665.2) | Nonsense Mutation (SNP) | VAF 21/251 reads (8%) | catalogued as COSV65017727; called by muse, mutect2
- AGBL1 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV69799914; called by muse, mutect2, varscan2
- AGBL1 | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs987316890, COSV69794360, COSV69799917; called by muse, mutect2
- AGBL1 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV66858883; called by muse, varscan2
- AGBL2 | c.1672C>T p.H558Y | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54092219; called by muse, mutect2, varscan2
- AGBL2 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs978075460, COSV100101136; called by muse, mutect2, varscan2
- AGBL4 | c.726G>A p.G242= | Splice Region (SNP) | VAF 3/10 reads (30%) | catalogued as COSV61892994; called by muse, mutect2
- AGFG1 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs1352514961, COSV59512133; called by muse, mutect2, varscan2
- AGGF1 | c.973C>T p.H325Y | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV57229179; called by muse, mutect2
- AGK | c.706C>T p.H236Y | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100814559, COSV62594580; called by muse, mutect2, varscan2
- AGL | c.553T>C p.F185L | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV99648330; called by muse, mutect2, varscan2
- AGMAT | c.470C>T p.T157I | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs376485013; called by muse, mutect2, varscan2
- AGO1 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV64595354; called by muse, varscan2
- AGO1 | c.1922C>T p.S641F | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV64595355; called by muse, mutect2, varscan2
- AGO2 | c.2317C>T p.R773C | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs777477236, COSV55047682; called by muse, mutect2, varscan2
- AGTPBP1 | c.3028C>T p.P1010S (on ENST00000357081 / NM_001330701.2; = p.P970S on NM_015239.2) | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV61271871; called by muse, mutect2, varscan2
- AGXT2 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV51485171, COSV51486498; called by muse, mutect2, varscan2
- AGXT2 | c.962A>G p.E321G | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51486513; called by muse, mutect2, varscan2
- AGXT2 | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as rs1221957742, COSV51486537; called by muse, mutect2, varscan2
- AHCTF1 | c.1487C>T p.P496L (on ENST00000366508; = p.P470L on NM_015446.5) | Missense Mutation (SNP) | VAF 68/281 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs1388066203, COSV58250439; called by muse, mutect2, varscan2
- AHCY | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV54153272; called by muse, mutect2, varscan2
- AHNAK | c.15827C>T p.P5276L | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV99945261; called by muse, mutect2, varscan2
- AHNAK | c.15826C>T p.P5276S | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV57214845, COSV99945263; called by muse, mutect2, varscan2
- AHNAK | c.13147C>T p.P4383S | Missense Mutation (SNP) | VAF 94/338 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57214340; called by muse, varscan2
- AHNAK | c.3010C>T p.P1004S | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1349395379, COSV57214355; called by muse, mutect2, varscan2
- AHNAK | c.2633C>T p.P878L | Missense Mutation (SNP) | VAF 153/543 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57214365; called by muse, mutect2, varscan2
- AHNAK2 | c.15944T>C p.L5315P | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV60915911; called by muse, mutect2, varscan2
- AHNAK2 | c.12697G>A p.G4233S | Missense Mutation (SNP) | VAF 89/341 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.975); catalogued as COSV60915936; called by muse, mutect2, varscan2
- AHNAK2 | c.11815G>A p.E3939K | Missense Mutation (SNP) | VAF 111/421 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.144); catalogued as rs747142815, COSV60915961; called by muse, mutect2, varscan2
- AHNAK2 | c.11551C>T p.L3851F | Missense Mutation (SNP) | VAF 91/288 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.868); catalogued as COSV60915969; called by muse, mutect2, varscan2
- AHNAK2 | c.6980C>T p.S2327L | Missense Mutation (SNP) | VAF 104/529 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373144352, COSV100316817; called by muse, mutect2
- AHNAK2 | c.4501C>T p.P1501S | Missense Mutation (SNP) | VAF 50/376 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60915997; called by muse, varscan2
- AHNAK2 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as COSV60916002; called by muse, mutect2, varscan2
- AHNAK2 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.36); catalogued as COSV60916007; called by muse, mutect2, varscan2
- AHNAK2 | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV60916014; called by muse, mutect2, varscan2
- AHSG | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 43/242 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0.372); catalogued as COSV56607862; called by muse, mutect2, varscan2
- AHSP | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56528990; called by muse, varscan2
- AICDA | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.92); catalogued as rs373061990, COSV57563722, COSV57563879; called by muse, varscan2
- AICDA | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as rs775814283, COSV57564503; called by muse, varscan2
- AICDA | c.252G>A p.W84* | Nonsense Mutation (SNP) | VAF 25/82 reads (30%) | catalogued as COSV57564515; called by muse, mutect2, varscan2
- AICDA | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV57563615; called by muse, varscan2
- AIFM3 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.812); catalogued as COSV100104135; called by muse, mutect2, varscan2
- AIRE | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52394117; called by muse, mutect2, varscan2
- AIRE | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1244111501, COSV52394125; called by muse, mutect2, varscan2
- AIRE | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.538); catalogued as rs200359179; called by muse, varscan2
- AIRE | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV52394146; called by muse, mutect2, varscan2
- AIRE | c.1120G>A p.G374R | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.784); catalogued as rs753097871, COSV52393515; called by muse, mutect2, varscan2
- AJAP1 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.225); catalogued as rs752139495, COSV65450855; called by muse, mutect2, varscan2
- AJAP1 | c.1157G>A p.G386E | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65450860; called by muse, varscan2
- AJAP1 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1262017195, COSV65450863; called by muse, mutect2
- AK1 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as rs761274632, COSV99802298; called by muse, varscan2
- AK5 | c.1279G>A p.D427N (on ENST00000354567 / NM_174858.3; = p.D401N on NM_012093.4) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.791); catalogued as COSV60973189; called by muse, mutect2, varscan2
- AK7 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 68/221 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs112200493, COSV50871975; called by muse, mutect2, varscan2
- AK7 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV50872006, COSV99967400; called by muse, mutect2, varscan2
- AK7 | c.1392G>A p.M464I | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV50872033; called by muse, varscan2
- AK7 | c.1634G>A p.G545E | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.678); catalogued as COSV50872063; called by muse, mutect2, varscan2
- AK8 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.199); catalogued as COSV53754758; called by muse, varscan2
- AKAP1 | c.1129C>T p.Q377* | Nonsense Mutation (SNP) | VAF 17/116 reads (15%) | catalogued as COSV58470455, COSV58471524; called by muse, mutect2, varscan2
- AKAP11 | c.3046C>T p.H1016Y | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV50297106; called by muse, mutect2, varscan2
- AKAP12 | c.2854G>A p.E952K | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53575469; called by muse, mutect2, varscan2
- AKAP13 | c.3188C>T p.S1063F | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV63457834; called by muse, mutect2
- AKAP13 | c.3499C>T p.H1167Y | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.043); catalogued as rs771647350, COSV63457839; called by muse, mutect2, varscan2
- AKAP4 | c.1783G>A p.A595T | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as COSV62074515; called by muse, mutect2, varscan2
- AKAP4 | c.1537G>A p.G513R | Missense Mutation (SNP) | VAF 96/156 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as COSV62074522; called by muse, mutect2, varscan2
- AKAP4 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 89/128 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62074237; called by muse, mutect2, varscan2
- AKAP6 | c.1718C>T p.S573F | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV55214434; called by muse, mutect2, varscan2
- AKAP6 | c.4015C>T p.L1339F | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as rs1364594740, COSV55214455, COSV55232693; called by muse, mutect2, varscan2
- AKAP6 | c.4405G>A p.D1469N | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55214462; called by muse, varscan2
- AKAP6 | c.4446G>A p.M1482I | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as COSV55214471; called by muse, varscan2
- AKAP6 | c.4955G>A p.R1652Q | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763532229, COSV55208487; called by muse, mutect2, varscan2
- AKAP6 | c.5572G>A p.E1858K | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as COSV55214489; called by muse, mutect2, varscan2
- AKAP6 | c.6884C>T p.P2295L | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.738); catalogued as rs748002228, COSV55214500; called by muse, mutect2, varscan2
- AKAP9 | c.9815C>T p.S3272L (on ENST00000359028; = p.S3248L on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/78 reads (69%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.83); catalogued as COSV62344044; called by muse, varscan2
- AKNA | c.3908C>T p.S1303F | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV56337023; called by muse, mutect2, varscan2
- AKNA | c.3002C>T p.P1001L | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV56312710; called by muse, mutect2, varscan2
- AKNA | c.2650C>T p.Q884* | Nonsense Mutation (SNP) | VAF 23/85 reads (27%) | catalogued as COSV56312716; called by muse, mutect2, varscan2
- AKNAD1 | c.1615G>A p.G539R | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.142); catalogued as rs747543823, COSV62198743; called by muse, mutect2, varscan2
- AKR1B15 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.312); catalogued as rs1424813344, COSV71151463, COSV71151951; called by muse, varscan2
- AKR1C2 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as rs1427588836, COSV101060370; called by mutect2, varscan2
- AKR1C3 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as rs1554786246; called by muse, mutect2, varscan2
- AKR1C3 | c.910C>T p.H304Y | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV101003038, COSV65910520; called by muse, mutect2, varscan2
- AKR1C4 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as rs781788408, COSV54122205; called by muse, mutect2, varscan2
- AKR1E2 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.034); catalogued as rs1564265691, COSV53630574; called by muse, mutect2, varscan2
- AKR7A2 | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs79772073, COSV52515521; called by muse, mutect2, varscan2
- AKR7A2 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.319); catalogued as rs772462863, COSV52516178; called by mutect2, varscan2
- AL121899.2 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV67350753; called by muse, varscan2
- AL121899.2 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 62/227 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as rs753489818, COSV67350760; called by muse, varscan2
- AL358113.1 | c.3296G>A p.R1099Q | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.105); catalogued as rs150494393; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AL592490.1 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV69426364; called by muse, mutect2
- AL592490.1 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.96); catalogued as COSV69426378; called by muse, mutect2
- AL645922.1 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54960693; called by muse, varscan2
- AL645922.1 | c.1669G>A p.G557S | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54960719; called by muse, mutect2, varscan2
- AL645922.1 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.667); catalogued as COSV54960720; called by muse, varscan2
- AL645922.1 | c.1907G>A p.G636D | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs762998024, COSV54960723; called by muse, varscan2
- AL669918.1 | c.2302G>A p.G768R | Missense Mutation (SNP) | VAF 68/240 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV71271017; called by muse, varscan2
- ALAD | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770484660, COSV52959008; called by muse, mutect2, varscan2
- ALCAM | c.538C>T p.L180F | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.327); catalogued as rs1233060600, COSV60246691; called by muse, mutect2, varscan2
- ALDH1A1 | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52791458; called by muse, mutect2, varscan2
- ALDH1A2 | c.558G>A p.W186* | Nonsense Mutation (SNP) | VAF 18/79 reads (23%) | catalogued as COSV51078839; called by muse, mutect2, varscan2
- ALDH1A2 | c.425G>A p.G142D | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.483); catalogued as COSV99990233; called by muse, mutect2, varscan2
- ALDH1A2 | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.046); catalogued as COSV99990247; called by muse, mutect2, varscan2
- ALDH1A3 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV60901785; called by muse, mutect2
- ALDH1B1 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV66619755; called by muse, varscan2
- ALDH1L1 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as rs751676222, COSV56414209; called by muse, mutect2, varscan2
- ALDH1L1 | c.408G>A p.W136* | Nonsense Mutation (SNP) | VAF 33/155 reads (21%) | catalogued as rs752886087, COSV56411823; called by muse, mutect2, varscan2
- ALDH1L1 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV56414253; called by muse, mutect2, varscan2
- ALDH3A1 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as rs774582773, COSV56735365; called by muse, mutect2, varscan2
- ALDH3B2 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs745389018, COSV62428159; called by muse, mutect2, varscan2
- ALDH4A1 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs750304455, COSV51892757; called by muse, mutect2, varscan2
- ALDH5A1 | c.609+1G>A p.X203_splice | Splice Site (SNP) | VAF 19/61 reads (31%) | catalogued as COSV62373612; called by muse, varscan2
- ALDH7A1 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV68629124; called by muse, mutect2, varscan2
- ALDOA | c.1231C>T p.L411F (on ENST00000642816 / NM_001243177.4; = p.L357F on NM_184041.5) | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57632828; called by muse, mutect2, varscan2
- ALDOB | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs763044110, COSV66397874; called by mutect2, varscan2
- ALDOB | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.847); catalogued as COSV66397880; called by muse, mutect2, varscan2
- ALDOB | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs780352710, COSV66397883; called by muse, mutect2, varscan2
- ALG13 | c.2908C>T p.P970S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52639295; called by muse, mutect2, varscan2
- ALG8 | c.1445C>T p.S482F | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.49); catalogued as COSV55200475; called by muse, mutect2, varscan2
- ALG9 | c.1444C>T p.P482S (on ENST00000614444 / NM_001352418.1; = p.P489S on NM_024740.2) | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV67644431; called by muse, mutect2, varscan2
- ALK | c.4481G>A p.G1494E | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.344); catalogued as rs368484630; ClinVar: uncertain significance; called by muse, varscan2
- ALK | c.4064C>T p.P1355L | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66568912; called by muse, mutect2, varscan2
- ALK | c.2606G>A p.G869E | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101200913; called by muse, mutect2, varscan2
- ALK | c.2605G>A p.G869R | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101200915; called by muse, mutect2, varscan2
- ALK | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs1486167712, COSV66568938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALKBH3 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57024215; called by muse, mutect2, varscan2
- ALKBH4 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs777078094, COSV52961020; called by muse, mutect2, varscan2
- ALMS1 | c.2996C>T p.P999L | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs942317797, COSV52510322; called by muse, mutect2, varscan2
- ALMS1 | c.3377C>T p.A1126V | Missense Mutation (SNP) | VAF 53/291 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.009); catalogued as COSV52510334; called by muse, mutect2, varscan2
- ALMS1 | c.6422C>T p.S2141F | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.234); catalogued as COSV52510361; called by muse, mutect2, varscan2
- ALOX12B | c.1799G>A p.R600Q | Missense Mutation (SNP) | VAF 96/242 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.136); catalogued as rs1333287390, COSV59871261; called by muse, mutect2, varscan2
- ALOX12B | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as rs1466188561, COSV59871201; called by muse, varscan2
- ALOX5 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); catalogued as rs372480343; called by muse, mutect2, varscan2
- ALPG | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV54966164; called by muse, mutect2, varscan2
- ALPG | c.879G>A p.M293I | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99779120; called by muse, mutect2, varscan2
- ALPK1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 54/268 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51585294; called by muse, mutect2, varscan2
- ALPK1 | c.2215C>T p.Q739* | Nonsense Mutation (SNP) | VAF 40/107 reads (37%) | catalogued as COSV51585314; called by muse, varscan2
- ALPK1 | c.2228C>T p.A743V | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs763635594, COSV51585322; called by muse, varscan2
- ALPK2 | c.5395G>A p.E1799K | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV64493187; called by muse, varscan2
- ALPK2 | c.5258C>T p.A1753V | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV64493194; called by muse, mutect2, varscan2
- ALPK2 | c.5128G>A p.E1710K | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs758307277, COSV64490250; called by muse, varscan2
21,674 further variants in this file (13,275 protein-altering or splice-affecting, 7,878 silent, 521 other) are not listed here.
